Somatic mutation profile of tumor specimen MP2PRT-PAVBIU-TMP1-A (aliquot MP2PRT-PAVBIU-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVBIU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,382 days).
Specimen MP2PRT-PAVBIU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26c47e09-5dc3-41e6-a6c5-e439e9f7ee2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVBIU-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVBIU-NB1-B-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7f9b3cb-29ed-4b63-924a-a31fec8d8edf

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP13A5 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs370567338; called by muse, mutect2, varscan2
- CPXM2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754686014, COSV53856331; called by muse, mutect2, varscan2
- PRUNE2 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100944965; called by muse, mutect2, varscan2
- ZFP36L2 | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 160/474 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56697653; called by muse, mutect2, varscan2
- APBA1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 225/596 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARHGEF38 | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- NR1H2 | c.500_516delinsGAAGAAGATTCGGAAACAG p.K167Rfs*54 | Frame Shift Ins (INS) | VAF 3/35 reads (9%) | called by mutect2*, pindel
- CDRT15L2 | c.198G>A p.S66= | Silent (SNP) | VAF 169/404 reads (42%) | catalogued as rs557578499; called by muse, mutect2, varscan2
- MUC16 | c.18780G>A p.A6260= | Silent (SNP) | VAF 105/359 reads (29%) | catalogued as rs370104717; called by muse, mutect2, varscan2
- SCN5A | c.3987C>T p.G1329= (on ENST00000333535 / NM_198056.3; = p.G1328= on NM_000335.5) | Silent (SNP) | VAF 105/327 reads (32%) | catalogued as rs761384669, COSV61114798; ClinVar: likely benign; called by muse, mutect2, varscan2
